Gene-level copy-number profile of tumor specimen C3L-00098-02 from CPTAC case C3L-00098, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 63.5 years (23,197 days).
Specimen C3L-00098-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8eaf3876-c540-447d-a6c8-2f5b1e9c20ae.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00098-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/09044a96-9221-4edf-aa62-234467ac3243

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 50; copy number 1: 66; copy number 2: 19,837; copy number 3: 10,279; copy number 4: 23,524; copy number 5: 1,666; copy number 6: 1,301; copy number 7: 375; copy number 8: 821; copy number 9: 87; copy number 10: 20; copy number 11: 176; copy number 12: 113; copy number 14: 24; copy number 16: 49.

Homozygous deletions (total copy number 0; autosomes only): 50 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,190,901–7,267,536, 6 genes: RPS3AP33, AF228730.1, AF228730.3, OR7E125P, FAM90A15P, FAM90A3P.
- chr11:11,856,490–11,856,859, 1 gene (within-gene range 0–2): H3P33.
- chr15:19,987,656–20,096,029, 10 genes: IGHV3OR15-7, IGHD5OR15-5A, IGHD4OR15-4A, IGHD3OR15-3A, IGHD2OR15-2A, IGHD1OR15-1A, FAM30B, AC127381.1, BCAR1P1, RN7SL584P.
- chr15:20,826,454–21,058,440, 18 genes (within-gene range 0–3): AC012414.1, MIR3118-2, POTEB2, RNU6-749P, AC012414.5, AC037471.2, ZNF519P2, NF1P1, MIR5701-1, LINC01193, OR11J2P, OR11J5P, IGHD5OR15-5B, IGHD4OR15-4B, IGHD3OR15-3B, IGHD2OR15-2B, IGHD1OR15-1B, FAM30C.
- chr15:98,784,426–98,784,502, 1 gene (within-gene range 0–2): MIR4714.
- chr16:89,443,318–89,459,437, 2 genes (within-gene range 0–2): RNU6-430P, AC092120.2.
- chr17:48,635,923–48,733,888, 12 genes: AC103702.2, LINC02086, AC091179.2, RPL9P28, COX6B1P2, PRAC1, PRAC2, AC091179.3, AC091179.4, MIR3185, HOXB13, AC091179.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 469 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:1,692,731–1,982,207, 7 genes, copy number 9 (within-gene range 6–9): SLBP, AC016773.1, TACC3, TMEM129, FGFR3, LETM1, NSD2.
- chr6:54,307,859–55,282,620, 11 genes, copy number 9: TINAG, TINAG-AS1, CLNS1AP1, RPL10P10, RPSAP44, KRASP1, RNU6-1023P, AL512363.1, FAM83B, AL049555.1, HCRTR2.
- chr6:55,680,642–55,681,021, 1 gene, copy number 9: AL590290.1.
- chr8:94,249,253–94,793,836, 17 genes, copy number 9 (within-gene range 7–9): GEM, RPS4XP10, RAD54B, FSBP, VIRMA, AC023632.5, AC023632.2, AC023632.1, AC023632.3, AC023632.4, AC108860.2, ESRP1, Metazoa_SRP, AC108860.1, AP005660.1, Y_RNA, DPY19L4.
- chr8:140,657,900–141,308,305, 12 genes, copy number 10 (within-gene range 8–10): PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3.
- chr10:72,636,497–72,887,694, 8 genes, copy number 10: HMGN2P34, AL513185.3, Y_RNA, MCU, MIR4676, AC016542.3, AC016542.2, AC016542.1.
- chr17:31,583,162–35,009,743, 99 genes, copy number 12 (within-gene range 4–12) (broad region; genes not listed).
- chr17:36,591,879–41,734,644, 251 genes, copy number 11–16 (broad region; genes not listed).
- chr19:13,731,760–14,496,149, 47 genes, copy number 9: CCDC130, MRI1, AC008686.1, C19orf53, ZSWIM4, AC020916.2, RN7SL619P, AC020916.1, MIR24-2, MIR27A, MIR23A, NANOS3, MIR181C, MIR181D, C19orf57, CC2D1A, PODNL1, DCAF15, RFX1, AC022098.4, RLN3, AC022098.2, IL27RA, PALM3, EEF1DP1, MISP3, MIR1199, C19orf67, SAMD1, PRKACA, AC022098.3, ASF1B, AC022098.1, ADGRL1, RN7SL231P, AC011509.2, AC011509.1, LINC01841, LINC01842, ADGRE5, AC008569.1, DDX39A, PKN1, AC008569.2, PTGER1, GIPC1, SNRPGP15.
- chr19:55,181,247–55,221,616, 3 genes, copy number 9: PTPRH, AC010327.7, AC010327.5.
- chr20:61,953,469–62,308,862, 12 genes, copy number 11 (within-gene range 7–11): TAF4, MIR1257, AL137077.1, MIR3195, LSM14B, PSMA7, SS18L1, MTG2, HRH3, OSBPL2, ADRM1, AL354836.1.
- chr22:29,099,041–29,111,683, 1 gene, copy number 9 (within-gene range 6–9): AL021393.1.

Autosomal genes at a single copy (total copy number 1): 66. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
